TCGA case TCGA-43-A56V — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bb2a7057-6df5-4eb9-ad0f-9ac47314889e

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.2; Tissue or organ of origin: Middle lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 61.5 years (22,475 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 366 days (1.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Docetaxel; Days to treatment start: 47 days; Days to treatment end: 111 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Synchronous primary of the lung (histology not recorded by GDC). Laterality: Left; Age at diagnosis: 61.4 years (22,425 days); Days to diagnosis: -50 days; AJCC staging edition: 7th; AJCC pathologic stage: Stage IB.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 141 days; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 62.5 years (22,830 days); Days to diagnosis: 355 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (6 entries)
- Days to follow up: 154 days; Disease response: Tumor Free.
- Day 355 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 355 days; Evidence of progression type: Convincing Image Source.
- Day 355 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 355 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 366 days (1.0 years); Disease response: With Tumor.
- Karnofsky performance status: 70; Timepoint: Other.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 58; FEV1/FVC after bronchodilator (%): 97; FEV1/FVC before bronchodilator (%): 97; FEV1 after bronchodilator (% of reference): 76; FEV1 before bronchodilator (% of reference): 78.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 48; Tobacco smoking onset year: 1967; Tobacco smoking quit year: 1999.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-43-A56V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 280 mg.
  Slide TCGA-43-A56V-01A-01-TSA: Section location: Top; Percent tumor cells: 67; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 30; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 1.
- Sample TCGA-43-A56V-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-43-A56V-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Middle; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxotere.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form, New neoplasm event types: New tumor event type: Locoregional Recurrence; New tumor event type: Distant Metastasis.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lung.
- Other malignancy form, Radiation treatment: History radiation treatment to site of TCGA tumor: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 366 days; disease-specific survival: no event (censored), 366 days; disease-free interval: event (new tumor event after initially disease-free), 355 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 355 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-43-A56V-01A-11D-A26L-01): tumor purity 0.57, ploidy 1.75, whole-genome doublings 0.
